Somatic mutation profile of tumor specimen BLGSP-71-08-00034-01A (aliquot BLGSP-71-08-00034-01A-01D-A671-33) from CGCI case BLGSP-71-08-00034, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-08-00034-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Ovary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d6aaa70-08c3-4ffd-b38b-8e4e4a2d001b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00034-12A (Buccal Cell Normal), aliquot BLGSP-71-08-00034-12A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7451ec59-7d70-45f1-b827-21d1024202a5

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 223/578 reads (39%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, varscan2
- DDX3X | c.1066T>G p.F356V (on ENST00000399959; = p.F357V on NM_001356.5) | Missense Mutation (SNP) | VAF 216/460 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67863677, COSV67864841; called by muse, varscan2
- AC072022.2 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 62/142 reads (44%) | called by muse, varscan2
- ETS1 | c.71T>C p.F24S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GNA13 | c.417_418del p.R140Gfs*23 | Frame Shift Del (DEL) | VAF 269/405 reads (66%) | called by mutect2, pindel, varscan2
- SIN3A | c.2458A>C p.I820L | Missense Mutation (SNP) | VAF 38/643 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2
- TFAP4 | c.552C>A p.Y184* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- AC072022.2 | c.-1A>C | 5'UTR (SNP) | VAF 42/95 reads (44%) | catalogued as COSV104434031, COSV69206782; called by muse, varscan2
- MYC | c.-56C>T | 5'UTR (SNP) | VAF 52/126 reads (41%) | catalogued as COSV52373833, COSV52373912; called by muse, mutect2, varscan2
